Somatic mutation profile of tumor specimen TCGA-KL-8340-01A (aliquot TCGA-KL-8340-01A-11D-2310-10) from TCGA case TCGA-KL-8340, project TCGA-KICH (Kidney Chromophobe). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, chromophobe type; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage II; Age at diagnosis: 34.8 years (12,696 days).
Specimen TCGA-KL-8340-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6122edf5-f81a-4c07-a23b-7a58bb99ae0c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KL-8340-11A (Solid Tissue Normal), aliquot TCGA-KL-8340-11A-01D-2310-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7d98710f-8925-4b49-b314-25a719aa1610

The open-access MAF lists 14 somatic variants for this specimen: 10 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 2, 3'Flank 1, Splice Region 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKT1S1 | c.458A>T p.D153V (on ENST00000344175 / NM_001098633.4; = p.D173V on NM_032375.5) | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100465135; called by muse, mutect2
- CFAP54 | c.5064C>A p.D1688E | Missense Mutation (SNP) | VAF 14/280 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as rs1183237987, COSV100733103, COSV61574800; called by muse, mutect2
- CYP21A2 | c.738+6G>T | Splice Region (SNP) | VAF 10/240 reads (4%) | catalogued as COSV64479760; called by muse, mutect2
- ELAVL4 | c.469C>T p.R157C | Missense Mutation (SNP) | VAF 13/174 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs138779266; called by muse, mutect2
- PCDHGB1 | c.1633C>T p.R545C | Missense Mutation (SNP) | VAF 10/133 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.262); catalogued as COSV99536286; called by muse, mutect2
- SLC4A5 | c.3085G>A p.A1029T | Missense Mutation (SNP) | VAF 9/130 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100697593; called by muse, mutect2
- SSX3 | c.237C>A p.F79L | Missense Mutation (SNP) | VAF 13/378 reads (3%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV53643279; called by muse, mutect2
- ICE1 | c.5483A>G p.Q1828R | Missense Mutation (SNP) | VAF 17/112 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- NCAPH | c.1882G>C p.V628L | Missense Mutation (SNP) | VAF 34/58 reads (59%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.576); called by muse, mutect2, varscan2
- PHACTR1 | c.95G>A p.G32E | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- LMCD1 | c.285G>A p.K95= | Silent (SNP) | VAF 46/134 reads (34%) | called by muse, mutect2, varscan2
- TCP1 | c.1470G>A p.L490= | Silent (SNP) | VAF 36/102 reads (35%) | called by muse, mutect2, varscan2
- EIF5AL1 | c.*3306C>T | 3'UTR (SNP) | VAF 8/56 reads (14%) | catalogued as rs3827877; called by mutect2, varscan2
- SLCO2A1 | chr3:133928577 G>A | 3'Flank (SNP) | VAF 24/124 reads (19%) | catalogued as rs1194964728, COSV60483629; called by muse, mutect2, varscan2
